Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A238, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A238-01A (Primary Tumor).

[page 1 of 4]
	lw 4/8/11	

Print this Page

Specimen Description

404-0-3

carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 lw 4/8/11

Surgical Pathology Report

Patient Name: [REDACTED]
Accession #: [REDACTED]
Med. Rec #: [REDACTED]
Submitting Physician: [REDACTED]

*******Clinical History*******

Patient History and Preoperative Diagnosis: Right thyroid nodule.

*******Final Pathologic Diagnosis*******

- A. Lymph node, Delphian, biopsy:
- Lymph node (0/1), no tumor seen.
- B. Thyroid, total thyroidectomy:
- Papillary thyroid carcinoma, multifocal (see synoptic report).

*****Electronically Signed By*****

*******Synoptic Report*********SYNOPTIC REPORT FOR THYROID CANCER:**

Specimen type: Total thyroidectomy.

Tumor location: Main (largest) tumor is located in the right thyroid lobe.
Tumor size: 3.9 x 2.7 x 2.0 cm (largest mass); plus two additional foci of papillary microcarcinoma: one in the right lobe measuring 0.5 cm. in greatest diameter, and a second one in the left lobe measuring 0.2 cm. in greatest diameter.

Histologic type: Papillary carcinoma.

Tumor grade: Well-differentiated.

Lymphatic/vascular invasion: Yes.

Capsular invasion: Yes, extensive.

Tumor extent:

Confined to the thyroid: No; tumor infiltrates perithyroidal soft tissue and reaches up to the inked outer surface of the specimen.

Multifocal: Yes.

Invasion of thyroid cartilage or hyoid bone: No.

Lymph nodes: N/A.

Additional pathologic findings: None.

pTNM: pT3NxMx.

Comments: In some areas, the tumor shows focally features of "tall cell"

[page 2 of 4]
Specimen Description

Surgical Pathology Report

*******Clinical History*******

Patient History and Preoperative Diagnosis: Right thyroid nodule.

*******Final Pathologic Diagnosis*******

- A. Lymph node, Delphian, biopsy:
- Lymph node (0/1), no tumor seen.
- B. Thyroid, total thyroidectomy:
- Papillary thyroid carcinoma, multifocal (see synoptic report).

*******Synoptic Report*******

SYNOPTIC REPORT FOR THYROID CANCER:

Specimen type: Total thyroidectomy.

Tumor location: Main (largest) tumor is located in the right thyroid lobe.

Tumor size: 3.9 x 2.7 x 2.0 cm (largest mass); plus two additional foci of papillary microcarcinoma: one in the right lobe measuring 0.5 cm. in greatest diameter, and a second one in the left lobe measuring 0.2 cm. in greatest diameter.

Histologic type: Papillary carcinoma.

Tumor grade: Well-differentiated.

Lymphatic/vascular invasion: Yes.

Capsular invasion: Yes, extensive.

Tumor extent:

Confined to the thyroid: No; tumor infiltrates perithyroidal soft tissue and reaches up to the inked outer surface of the specimen.

Multifocal: Yes.

Invasion of thyroid cartilage or hyoid bone: No.

Lymph nodes: N/A.

[page 3 of 4]
Additional pathologic findings: None.

pTNM: pT3NxMx.

Comments: In some areas, the tumor shows focally features of "tall cell" variant of papillary carcinoma.

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists and the Association of Directors of Anatomic and Surgical Pathology for the reporting of cancer specimens

*****INTRAOPERATIVE CONSULTATION DIAGNOSIS:*****

AF1. Delphian lymph node: (FROZEN SECTION PERFORMED)
- No tumor identified.

BF1. Thyroid: (FROZEN SECTION PERFORMED)
- Papillary carcinoma.

Examining pathologist: [REDACTED]

*****SPECIMEN(S) RECEIVED:*****

A: Lymph node, ENT, REG

B: Thyroid, REG

*****GROSS DESCRIPTION:*****

The specimens are received in two properly labeled containers, which are frozen sections, with the patient's name and accession number.

A. The specimen is designated "Delphian lymph node" and consists of a 0.6 x 0.4 x 0.3 cm tan-pink lymph node. The entire specimen is submitted for frozen section and frozen section in cassette AF1 is resubmitted as received. TE 1

B. The specimen is designated "thyroid" and consists of a 5.0 x 3.5 x 3.5 cm thyroid gland that weighs 17 grams. The outer surface is tan-purple smooth and glistening. The entire specimen is inked black and the specimen is serially sectioned to reveal a 3.9 x 2.7 x 2.0 cm well-circumscribed tan firm nodule present in the right thyroid lobe that grossly abuts the black inked capsular surface. The nodule is hemorrhagic over approximately 40%. The right lobe also displays a separate 0.5 x 0.3 x 0.3 cm tan-white well-circumscribed nodule which is located 1.0 cm from the largest nodule. The left lobe of the thyroid contains a 0.2 x 0.2 x 0.2 cm tan-white well circumscribed nodule that grossly abuts the black inked capsular surface. This nodule is located 2.4 cm from the largest nodules. The remaining thyroid parenchyma is dark red and rubbery with no other discrete lesions identified. A representative section of the largest nodule is submitted for frozen section and frozen section cassette BF1 is resubmitted as received. (P) RS 17

Summary of Cassettes: BF1, representative section, frozen section;

[page 4 of 4]
B1-11, entire largest nodule; B12, entire smaller nodule, right lobe; B13, entire smaller nodule, left lobe; B14, uninvolved left lobe; B15, uninvolved isthmus; B16, uninvolved right lobe

Lab Use Only: [REDACTED]

Gross description by: [REDACTED]

[REDACTED]
Top of

Source: NCI Genomic Data Commons file 8ad1c9b7-50d1-43c5-a7cd-cd8160e55a43 (TCGA-FE-A238.126D792D-DD12-4526-995D-02AE90FE3AAD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).